Somatic mutation profile of tumor specimen C3N-01385-02 (aliquot CPT0162230035) from CPTAC case C3N-01385, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 66.8 years (24,392 days).
Specimen C3N-01385-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 428003f1-dfb6-414b-a43a-722e45ceacac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01385-31 (Blood Derived Normal), aliquot CPT0162290002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bbfddcd2-3a7c-453d-80b8-896395908c74

The open-access MAF lists 19 somatic variants for this specimen: 10 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 8, Missense Mutation 7, Nonsense Mutation 2, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 16/341 reads (5%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- MRC2 | c.3758G>A p.R1253Q | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.207); catalogued as rs754204879, COSV57637352; called by muse, mutect2
- PCDHGA3 | c.1513G>A p.V505I | Missense Mutation (SNP) | VAF 19/305 reads (6%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.044); catalogued as COSV53891908; called by muse, mutect2
- PCLO | c.4837C>T p.R1613* | Nonsense Mutation (SNP) | VAF 9/245 reads (4%) | catalogued as COSV61626730; called by muse, mutect2
- QSER1 | c.2558A>G p.D853G (on ENST00000399302; = p.D982G on NM_001076786.3) | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV67901641; called by muse, mutect2
- ANGPTL4 | c.764T>C p.F255S | Missense Mutation (SNP) | VAF 25/476 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.936); called by muse, mutect2
- BCOR | c.850_853del p.D284Kfs*93 | Frame Shift Del (DEL) | VAF 10/105 reads (10%) | called by mutect2, pindel
- GAS2L3 | c.1900A>G p.T634A | Missense Mutation (SNP) | VAF 8/229 reads (3%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2
- HCN2 | c.1399C>T p.Q467* | Nonsense Mutation (SNP) | VAF 11/333 reads (3%) | called by muse, mutect2
- MXRA8 | c.356A>T p.N119I | Missense Mutation (SNP) | VAF 16/303 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- CYB561 | c.492T>C p.G164= | Silent (SNP) | VAF 11/212 reads (5%) | called by muse, mutect2
- GPR156 | c.663C>T p.S221= | Silent (SNP) | VAF 12/171 reads (7%) | catalogued as rs746327876, COSV100251459, COSV59940971; called by muse, mutect2
- PARD6A | c.489T>C p.H163= | Silent (SNP) | VAF 8/120 reads (7%) | called by muse, mutect2
- PPP6R2 | c.1788G>A p.P596= (on ENST00000216061 / NM_001365836.1; = p.P569= on NM_014678.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 14/222 reads (6%) | catalogued as rs745576705; called by muse, mutect2
- TIGAR | c.12C>T p.F4= | Silent (SNP) | VAF 14/218 reads (6%) | catalogued as rs1366407595, COSV99463857; called by muse, mutect2
- TLCD3B | c.366G>A p.A122= | Silent (SNP) | VAF 17/289 reads (6%) | catalogued as rs148555089; called by muse, mutect2
- ZEB2 | c.468C>T p.R156= | Silent (SNP) | VAF 9/179 reads (5%) | catalogued as rs1272829324, COSV57951614; called by muse, mutect2
- ZMYND10 | c.156C>T p.V52= | Silent (SNP) | VAF 11/209 reads (5%) | catalogued as COSV99204819; called by muse, mutect2
- ARHGEF4 | chr2:130915787 G>A | 5'Flank (SNP) | VAF 4/52 reads (8%) | catalogued as rs986148048; called by muse, mutect2
